Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A8GR, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A8GR-06A (Metastatic).

[page 1 of 2]
DIAGNOSIS

(A) SMALL INTESTINE, SEGMENTAL RESECTION:

METASTATIC MELANOMA, FORMING A 9.0 CM MASS IN THE SMALL INTESTINE. (SEE COMMENT)
THE TUMOR ULCERATES THE MUCOSA AND EXTENDS TO THE SUBSEROAL SOFT TISSUE.
LARGE VESSEL INVASION IS PRESENT.
No unequivocal lymphatic invasion is identified.
METASTATIC MELANOMA IS PRESENT IN ONE OF TWO LYMPH NODES (1/2).
Small intestinal and mesenteric soft tissue margins of resection are free of tumor.

(B) SMALL INTESTINE #2, SEGMENTAL RESECTION:

METASTATIC MELANOMA, FORMING A 2.3 CM MASS IN THE SMALL INTESTINE.
TUMOR FORMS AN ULCERATED POLYPOID MASS AND EXTENDS AT LEAST INTO THE SUBMUCOSA.
LYMPHOVASCULAR INVASION IS PRESENT.
Small intestinal margins are negative for tumor.
Additional segment of small intestine, no tumor present.

COMMENT

Immunohistochemical stains were for S-100 and pan-mel were performed. The neoplastic cells are diffusely positive for both markers.

Metastatic Tumor: A10

Normal: A2

*ICD O-3
Melanoma NOS 8720/3
Site Small intestine NOS C17.9
JW 11/27/13*

GROSS DESCRIPTION

(A) SEGMENT OF SMALL BOWEL - A segment of small bowel measuring 8.5 x 4 cm with a large tumor arising within the wall of the bowel and then invading into the mucosa (9 x 7 x 5 cm). The tumor appears to be covered with the serosal surface. The anterior of the tumor is hemorrhagic and necrotic. The tumor is 2 cm from one bowel margin and 1 cm from the opposite bowel margin. The bowel itself is unremarkable. A 1 cm positive lymph node is identified at the mesenteric margin.

INK CODE: Blue - serosal surface.

SECTION CODE: A1, bowel margin, en face; A2, opposite bowel margin, en face; A3, A4, mesenteric margin; A5, A6, one lymph node bisected at mesenteric margin; A7, A8, tumor with adjacent bowel; A9, tumor near serosal surface; A10, representative section of tumor.

(B) SEGMENT OF SMALL BOWEL #2 - Received are two fragments of bowel with (2.5 x 4 and 5 x 4.5 cm). Both fragments have stapled margins. The smaller fragment of tissue is unremarkable. Within the larger fragment of bowel is a large polypoid mass measuring 2.3 x 2 x 1.5 cm. This tumor is 0.5 cm from one of the stapled margins. The tumor appears to invade into the small intestinal wall. The serosal surface is focally puckered.

INK CODE: blue - serosal surface.

SECTION CODE: B1, smaller fragment of bowel mucosal margin with mesenteric margin; B2, smaller fragment of bowel opposite mucosal margin; B3-B5, tumor with closest mucosal margin.

CLINICAL HISTORY

Melanoma

CONSULTANT(S)

SNOMED CODES

T-58000, M-2706

[page 2 of 2]
-----END OF REPORT-----

HPPA Discrepancy		✓

Source: NCI Genomic Data Commons file 1de0d0c2-154f-40a5-897c-5435ee1e339c (TCGA-D3-A8GR.1C004953-8203-4865-8331-8C2A4224C129.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).